Somatic mutation profile of tumor specimen MP2PRT-PATVCE-TMP1-A (aliquot MP2PRT-PATVCE-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PATVCE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 2.2 years (799 days).
Specimen MP2PRT-PATVCE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eca1a99f-5b7b-4e32-b20f-114e9ce126d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATVCE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATVCE-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88123dba-b9ef-4d05-9053-660916773091

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Silent 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 45/323 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC011455.2 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 107/340 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs151116675; called by muse, mutect2, varscan2
- ADAMTS18 | c.3139C>T p.R1047* | Nonsense Mutation (SNP) | VAF 106/374 reads (28%) | catalogued as rs1011453043, COSV51400271; called by muse, mutect2, varscan2
- NLGN4X | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 96/199 reads (48%) | catalogued as COSV52011777, COSV52036003; called by muse, mutect2, varscan2
- PDZD2 | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 118/377 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763929150, COSV56851617; called by muse, mutect2, varscan2
- ZWINT | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 26/468 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs766487461; called by muse, mutect2
- ZYX | c.608C>G p.P203R | Missense Mutation (SNP) | VAF 145/571 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV59556098; called by muse, mutect2, varscan2
- ASH2L | c.638G>C p.R213T | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ELAPOR2 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 145/425 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HNF4G | c.69C>A p.H23Q (on ENST00000354370 / NM_001330561.2; = p.H70Q on NM_004133.5) | Missense Mutation (SNP) | VAF 28/457 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGHV4-59 | chr14:106627242 CACTGTGTCTC>GGAGG | Missense Mutation (DEL) | VAF 62/315 reads (20%) | called by pindel, varscan2*
- IGKV1OR2-108 | chr2:113406854 AGGATTATACTACCCCATTCACAGTGTTACAAGCCATAA>TTGGGGG | Missense Mutation (DEL) | VAF 57/141 reads (40%) | called by pindel, varscan2*
- PKD1L2 | c.2777A>G p.K926R | Missense Mutation (SNP) | VAF 108/372 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- LRP10 | c.795C>G p.L265= | Silent (SNP) | VAF 14/482 reads (3%) | called by muse, mutect2
- RWDD3 | c.708C>T p.V236= | Silent (SNP) | VAF 27/187 reads (14%) | called by muse, mutect2, varscan2
